Somatic mutation profile of tumor specimen TCGA-64-5775-01A (aliquot TCGA-64-5775-01A-01D-1625-08) from TCGA case TCGA-64-5775, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.3 years (26,058 days).
Specimen TCGA-64-5775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bad7aa24-1d36-4d5e-8766-34578be3d624.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-5775-10A (Blood Derived Normal), aliquot TCGA-64-5775-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05ac6fda-3c72-44c9-99c0-2b466ef1c2ab

The open-access MAF lists 535 somatic variants for this specimen: 407 protein-altering or splice-affecting, 113 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 333, Silent 113, Nonsense Mutation 29, Frame Shift Del 23, Splice Site 12, Intron 8, RNA 5, Splice Region 4, Frame Shift Ins 4, Nonstop Mutation 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 95/122 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV60918027; called by muse, mutect2, varscan2
- ACTL9 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555753425, COSV61004832; called by muse, mutect2, varscan2
- ADAD2 | c.1619T>G p.L540R (on ENST00000315906 / NM_001145400.2; = p.L622R on NM_139174.4) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99235638; called by muse, mutect2, varscan2
- ADAM19 | c.2525C>A p.P842H | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57438603; called by muse, mutect2, varscan2
- ADAMTS12 | c.4448G>T p.C1483F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61278096; called by muse, mutect2
- ADAMTS12 | c.4447-1G>T p.X1483_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61278105; called by muse, mutect2
- ADAMTSL3 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 94/173 reads (54%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV54467776; called by muse, mutect2, varscan2
- ADGRB2 | c.226A>T p.K76* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV57078528; called by muse, mutect2, varscan2
- ADGRB3 | c.3288-2A>T p.X1096_splice | Splice Site (SNP) | VAF 88/217 reads (41%) | catalogued as COSV53259129; called by muse, mutect2, varscan2
- ADGRG4 | c.8642C>A p.P2881Q | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV54966128; called by muse, varscan2
- ADH1C | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs772973805, COSV72463645; called by muse, mutect2, varscan2
- AGAP3 | c.2118G>C p.W706C (on ENST00000622464; = p.W742C on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68246580; called by muse, mutect2, varscan2
- AGRN | c.5161C>A p.L1721M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV65072168; called by muse, mutect2, varscan2
- AGTPBP1 | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV61277087; called by muse, mutect2, varscan2
- AHNAK | c.8104A>T p.I2702F | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV57224790, COSV57229143; called by muse, mutect2, varscan2
- AK5 | c.742C>A p.Q248K (on ENST00000354567 / NM_174858.3; = p.Q222K on NM_012093.4) | Missense Mutation (SNP) | VAF 153/189 reads (81%) | SIFT tolerated (0.2); PolyPhen benign (0.236); catalogued as COSV60980125, COSV60980774; called by muse, mutect2, varscan2
- AKAP10 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV56733014; called by muse, mutect2, varscan2
- AKAP13 | c.5458T>A p.C1820S (on ENST00000394518 / NM_007200.5; = p.C1824S on NM_006738.6) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV63468971; called by muse, mutect2, varscan2
- AKAP3 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs749128877, COSV57420287; called by muse, mutect2, varscan2
- AKNA | c.2917A>T p.R973W | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56314854; called by muse, mutect2, varscan2
- ALPK2 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV64496819; called by muse, mutect2, varscan2
- ANKH | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs374804595; called by muse, mutect2
- ANKRD1 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.166); catalogued as CM081517, COSV63310993; called by muse, mutect2
- ANKRD30A | c.1957C>A p.P653T (on ENST00000611781; = p.P597T on NM_052997.2) | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.901); catalogued as rs367966358, COSV64620280; called by muse, mutect2, varscan2
- ANKRD30A | c.2014C>A p.P672T (on ENST00000611781; = p.P616T on NM_052997.2) | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.901); catalogued as COSV64620289; called by muse, mutect2, varscan2
- AOX1 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV65983828; called by muse, mutect2, varscan2
- AP4E1 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1328098445, COSV55919899; called by muse, mutect2, varscan2
- API5 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV66635031; called by muse, mutect2, varscan2
- APOB | c.10142T>C p.L3381S | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51951054; called by muse, mutect2, varscan2
- ARHGAP6 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV61635302; called by muse, mutect2, varscan2
- ARHGEF3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs1438195552, COSV56332158; called by muse, mutect2, varscan2
- ARPP21 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51807603; called by muse, mutect2
- ASCC3 | c.1737G>T p.Q579H | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV61233421; called by muse, mutect2, varscan2
- ASPM | c.8892G>T p.W2964C | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.774); catalogued as rs201285805, COSV54138053; called by muse, mutect2, varscan2
- ASXL3 | c.4409C>A p.P1470Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52456427, COSV52473229; called by muse, mutect2, varscan2
- ATG4D | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as rs781286935, COSV58762708, COSV58762756; called by muse, mutect2, varscan2
- ATIC | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV52695268; called by muse, mutect2, varscan2
- ATM | c.2521G>T p.D841Y | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as CD982453, COSV53762235, COSV53772540; called by muse, mutect2, varscan2
- ATP8B4 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV52723627; called by muse, varscan2
- ATP9A | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV100124357, COSV58771495; called by muse, mutect2, varscan2
- BABAM2 | c.1058G>T p.W353L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100568758; called by muse, mutect2, varscan2
- BABAM2 | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100568761; called by muse, mutect2, varscan2
- BIRC6 | c.14378A>G p.H4793R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV70205333; called by muse, mutect2, varscan2
- BMP7 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs765434399, COSV101215720, COSV67782504; called by muse, mutect2, varscan2
- BOD1L1 | c.6754G>T p.G2252W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50059552; called by muse, mutect2
- BRD1 | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs376208895; called by muse, mutect2
- BRINP1 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV99776838; called by muse, mutect2, varscan2
- BRSK2 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57548666; called by muse, mutect2, varscan2
- BRWD3 | c.4507G>T p.A1503S | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); catalogued as COSV64753259; called by muse, mutect2, varscan2
- C11orf52 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV53715154; called by muse, mutect2, varscan2
- C1orf105 | c.199-1G>T p.X67_splice | Splice Site (SNP) | VAF 24/107 reads (22%) | catalogued as COSV62959323; called by muse, mutect2, varscan2
- C1orf105 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs1157834981, COSV100877983; called by muse, mutect2, varscan2
- C1orf116 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63944672; called by mutect2, varscan2
- C2CD6 | c.1663T>A p.L555I | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as COSV53800203; called by muse, mutect2, varscan2
- CACNA1C | c.5798A>T p.Q1933L (on ENST00000399634 / NM_001167625.1; = p.Q1862L on NM_000719.7) | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.018); catalogued as COSV59766895; called by muse, mutect2, varscan2
- CACNA1I | c.2466C>A p.D822E | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60817986; called by muse, mutect2, varscan2
- CACNA2D3 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55578747; called by muse, mutect2, varscan2
- CACNA2D4 | c.1188C>A p.C396* | Nonsense Mutation (SNP) | VAF 30/38 reads (79%) | catalogued as rs1555185483, COSV54959428; called by muse, mutect2, varscan2
- CACNG8 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV54414940, COSV54416630; called by muse, mutect2, varscan2
- CAMK1 | c.84-5G>A | Splice Region (SNP) | VAF 20/51 reads (39%) | catalogued as rs150915328; called by muse, mutect2, varscan2
- CAMKV | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56557648; called by muse, mutect2, varscan2
- CAPG | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55708755; called by muse, mutect2, varscan2
- CAPRIN1 | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100403816, COSV100404225; called by mutect2, varscan2
- CARD6 | c.1897A>G p.M633V | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs1359159536, COSV54568914; called by muse, mutect2, varscan2
- CAVIN4 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as COSV56868272; called by muse, mutect2, varscan2
- CCDC127 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV57257982, COSV99723191; called by muse, mutect2, varscan2
- CCDC178 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.141); catalogued as COSV100286590; called by muse, mutect2, varscan2
- CCDC83 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV99721965; called by muse, mutect2, varscan2
- CCDC87 | c.1480G>T p.V494F | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1041476035, COSV59580497; called by muse, mutect2, varscan2
- CCR2 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52749972; called by muse, mutect2, varscan2
- CD1E | c.752A>T p.Q251L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs1287721922, COSV63772766; called by muse, mutect2, varscan2
- CD6 | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV100533253; called by muse, mutect2, varscan2
- CDC73 | c.1480G>T p.V494L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV66470237; called by muse, mutect2, varscan2
- CDH23 | c.9617G>A p.R3206H | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs374156784, COSV99818761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH7 | c.1863G>C p.L621F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1048985365, COSV100541501, COSV59894015; called by muse, mutect2, varscan2
- CELF3 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV51885647; called by muse, mutect2, varscan2
- CELSR2 | c.7368G>T p.W2456C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762107951, COSV54779036; called by muse, mutect2, varscan2
- CENPH | c.313A>T p.R105W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51585677; called by muse, mutect2, varscan2
- CHEK2 | c.541A>G p.T181A (on ENST00000382580 / NM_001005735.2; = p.T138A on NM_007194.4) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1555927202, COSV60425797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHM | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV62566026; called by muse, mutect2, varscan2
- CHORDC1 | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 67/111 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57706914; called by muse, mutect2, varscan2
- CLEC4F | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55481466; called by muse, mutect2, varscan2
- CLVS1 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as COSV57982425; called by muse, mutect2, varscan2
- CMYA5 | c.8249C>T p.S2750L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV71409291; called by muse, mutect2
- COBL | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762527943, COSV54352988; called by muse, mutect2
- COL11A1 | c.2803C>A p.P935T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV62182128, COSV62188258; called by muse, mutect2, varscan2
- COL11A1 | c.887C>G p.A296G | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV62196156; called by muse, mutect2, varscan2
- COL11A1 | c.183C>A p.C61* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV62174966, COSV62196162; called by muse, mutect2, varscan2
- COL14A1 | c.1715C>G p.A572G | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV52867245, COSV99919316; called by muse, mutect2, varscan2
- COL15A1 | c.415A>T p.T139S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV66648960; called by muse, mutect2, varscan2
- COL1A2 | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM070816, COSV51964226; called by muse, mutect2, varscan2
- COL22A1 | c.1759-1G>C p.X587_splice | Splice Site (SNP) | VAF 19/121 reads (16%) | catalogued as COSV57358732; called by muse, mutect2, varscan2
- COL6A3 | c.3861C>G p.N1287K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV55080654, COSV55107902; called by muse, mutect2, varscan2
- CPNE5 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99782629, COSV99783272; called by muse, mutect2, varscan2
- CPNE5 | c.858G>T p.V286= | Splice Region (SNP) | VAF 8/29 reads (28%) | catalogued as rs1342144233, COSV99783275; called by muse, mutect2, varscan2
- CPS1 | c.1624A>T p.M542L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV51823521; called by muse, mutect2, varscan2
- CR1 | c.2748C>A p.S916R | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.983); catalogued as COSV65462828; called by muse, mutect2, varscan2
- CRB1 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as COSV66333313; called by muse, mutect2, varscan2
- CSF2RA | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV62626630; called by muse, mutect2, varscan2
- CSMD2 | c.7720C>A p.L2574M | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV53958429; called by muse, mutect2, varscan2
- CSMD3 | c.9287G>C p.C3096S (on ENST00000297405 / NM_001363185.1; = p.C2927S on NM_052900.3) | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52307660; called by muse, mutect2, varscan2
- CSMD3 | c.7072G>T p.A2358S (on ENST00000297405 / NM_001363185.1; = p.A2254S on NM_052900.3) | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV52124825, COSV52307678; called by muse, mutect2, varscan2
- CSN2 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.345); catalogued as COSV61992698; called by muse, mutect2, varscan2
- CTCFL | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1415844653, COSV54778757; called by muse, mutect2, varscan2
- CTSE | c.1204T>G p.*402Eext*11 (on ENST00000360218; = p.*397Eext*11 on NM_001910.4) | Nonstop Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV63061827; called by muse, mutect2, varscan2
- CTTNBP2 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV50471014; called by muse, mutect2, varscan2
- CYP2E1 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53312885; called by muse, mutect2, varscan2
- D2HGDH | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV58323332; called by muse, mutect2, varscan2
- DBF4 | c.1612A>G p.S538G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as COSV55996066, COSV55998895; called by muse, mutect2, varscan2
- DCAF12L2 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV63584099; called by muse, mutect2, varscan2
- DDC | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63567603; called by muse, mutect2
- DEF8 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51921255, COSV99240748; called by muse, mutect2, varscan2
- DGKI | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55973651; called by muse, mutect2
- DKKL1 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as rs371537751; called by muse, mutect2, varscan2
- DLGAP3 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1291733500, COSV52391941; called by muse, mutect2, varscan2
- DMRTB1 | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV65113973; called by muse, mutect2, varscan2
- DNAAF3 | c.1132G>T p.G378C (on ENST00000524407 / NM_001256715.2; = p.G425C on NM_178837.4) | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61279327; called by muse, mutect2, varscan2
- DNMT3B | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV52422858; called by muse, mutect2, varscan2
- DUS3L | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 35/45 reads (78%) | catalogued as rs770830758, COSV57832190, COSV57833543; called by muse, mutect2, varscan2
- ECPAS | c.2924C>A p.S975Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV52206956; called by muse, mutect2, varscan2
- EDRF1 | c.3365A>G p.Q1122R (on ENST00000356792 / NM_001202438.2; = p.Q1088R on NM_015608.2) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61766141; called by muse, mutect2
- EFCAB6 | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV53057967, COSV53071986; called by muse, mutect2, varscan2
- EFHC1 | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV64137722; called by muse, mutect2, varscan2
- EIF3A | c.2837G>C p.R946T | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64961357; called by muse, mutect2, varscan2
- ELAPOR2 | c.2514G>T p.R838S (on ENST00000450689 / NM_001142749.3; = p.R671S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV51891506; called by muse, mutect2, varscan2
- ELOVL2 | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61156986; called by muse, mutect2, varscan2
- EPHA4 | c.2370G>T p.W790C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56043504; called by muse, mutect2, varscan2
- ERC1 | c.2740G>C p.A914P (on ENST00000360905 / NM_178040.4; = p.A886P on NM_178039.4) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV61699261; called by muse, mutect2, varscan2
- ERICH3 | c.1846A>T p.R616* | Nonsense Mutation (SNP) | VAF 110/142 reads (77%) | catalogued as COSV58617408; called by muse, varscan2
- FAM131B | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.919); catalogued as COSV58374186; called by muse, mutect2, varscan2
- FAM131B | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV68126965; called by muse, mutect2, varscan2
- FAM160A2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 84/132 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs373467266; called by muse, mutect2, varscan2
- FAM47B | c.1127A>T p.K376M | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV61452734; called by muse, mutect2, varscan2
- FAM71B | c.1116G>T p.L372F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.092); catalogued as COSV57230852; called by muse, mutect2, varscan2
- FAT1 | c.13556A>C p.Y4519S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV71675863; called by muse, mutect2, varscan2
- FER | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV55304600; called by muse, mutect2, varscan2
- FGF14 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV104426119, COSV65957032; called by muse, mutect2, varscan2
- FGR | c.228G>A p.G76= | Splice Region (SNP) | VAF 7/23 reads (30%) | catalogued as COSV64969497, COSV64969729; called by muse, mutect2
- FOLR3 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61530877; called by muse, mutect2, varscan2
- FOXC2 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100234397; called by muse, mutect2, varscan2
- FREM2 | c.7053G>T p.M2351I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV54851276; called by muse, mutect2, varscan2
- FYN | c.503A>T p.N168I | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV57620686; called by muse, mutect2, varscan2
- FZD9 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60671328; called by muse, mutect2, varscan2
- GABRB1 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as COSV54998435; called by muse, mutect2, varscan2
- GALNT13 | c.1220G>T p.C407F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67237639; called by muse, mutect2, varscan2
- GLCCI1 | c.670T>A p.W224R | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99780729; called by muse, mutect2, varscan2
- GLCCI1 | c.671G>T p.W224L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99780732; called by muse, mutect2
- GOLGA5 | c.823A>C p.K275Q | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT tolerated (0.58); PolyPhen benign (0.046); catalogued as COSV50835720; called by muse, mutect2, varscan2
- GOLM2 | c.721+1G>T p.X241_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | catalogued as COSV55466233; called by muse, mutect2, varscan2
- GPBP1L1 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs375143538, COSV99322722; called by muse, mutect2, varscan2
- GPR32 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as COSV54515486; called by muse, mutect2, varscan2
- GPR37 | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58259467; called by muse, mutect2, varscan2
- GRIK2 | c.1789C>A p.P597T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs767151881, COSV100022612, COSV100029179; called by muse, mutect2, varscan2
- GRIK2 | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100029182; called by muse, mutect2, varscan2
- GRSF1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54657082; called by muse, mutect2, varscan2
- GTDC1 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54005630; called by muse, mutect2
- GTF3C1 | c.3690A>T p.R1230S | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV62244668; called by muse, mutect2, varscan2
- GUCY2C | c.1710+1G>T p.X570_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | catalogued as COSV53792771, COSV53795147; called by muse, mutect2, varscan2
- H1-4 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.968); catalogued as COSV56803397; called by muse, mutect2, varscan2
- HAPLN1 | c.898G>T p.G300* | Nonsense Mutation (SNP) | VAF 73/190 reads (38%) | catalogued as COSV57145273; called by muse, mutect2, varscan2
- HCRTR2 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100904074, COSV63798896; called by muse, mutect2, varscan2
- HDC | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51080336, COSV99984136; called by muse, mutect2, varscan2
- HDX | c.1664A>G p.E555G | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV52982566; called by muse, mutect2, varscan2
- HECTD4 | c.10478G>T p.C3493F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs753421097, COSV66399404; called by muse, mutect2, varscan2
- HINFP | c.1406A>T p.Q469L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV63432688; called by muse, mutect2, varscan2
- HOXA13 | c.957T>G p.Y319* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as COSV56084223; called by muse, mutect2, varscan2
- HSD3B2 | c.224T>A p.V75D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV65593985; called by muse, mutect2, varscan2
- HTR1A | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs757438767, COSV60500417, COSV60500551; called by muse, mutect2, varscan2
- HTR3A | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV55469547, COSV55471384; called by muse, mutect2, varscan2
- INTS6L | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66086196; called by muse, mutect2, varscan2
- INTS6L | c.1773G>C p.K591N | Missense Mutation (SNP) | VAF 73/88 reads (83%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.695); catalogued as COSV66086203; called by muse, mutect2, varscan2
- IQGAP3 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63254430; called by muse, mutect2, varscan2
- ITGAD | c.686C>A p.T229K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66760040; called by muse, mutect2, varscan2
- KANK4 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 41/517 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62989181; called by muse, mutect2
- KAT14 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs752139671, COSV66606487; called by muse, mutect2
- KCNA5 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs376977376; called by muse, mutect2, varscan2
- KCNC1 | c.1388C>A p.P463Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV56398195; called by muse, mutect2
- KCNC1 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56398209; called by muse, mutect2
- KCNE4 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV56055047; called by muse, mutect2, varscan2
- KCNU1 | c.3085C>A p.P1029T | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV67759624; called by muse, mutect2, varscan2
- KDR | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs767560921, COSV55775305; called by muse, mutect2, varscan2
- KIF2B | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52135057; called by muse, mutect2, varscan2
- KIR2DL3 | c.817A>T p.K273* | Nonsense Mutation (SNP) | VAF 34/46 reads (74%) | catalogued as rs1171764719, COSV60900609; called by muse, mutect2
- KIR3DL1 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201795773; called by muse, mutect2
- KLKB1 | c.1776G>T p.L592F | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52999129; called by muse, mutect2, varscan2
- KMT2A | c.11217C>G p.H3739Q | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV63292194; called by muse, mutect2, varscan2
- KRT23 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 85/113 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV52928912; called by muse, mutect2, varscan2
- KRTAP12-1 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1555948159, COSV100555381; called by muse, mutect2, varscan2
- LAMA1 | c.7429G>T p.V2477L | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV67543956; called by muse, mutect2, varscan2
- LATS2 | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV66879494; called by muse, mutect2, varscan2
- LELP1 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV64202732; called by muse, mutect2, varscan2
- LEPR | c.2913G>T p.E971D | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV62751060; called by muse, mutect2, varscan2
- LEPR | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 174/209 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62751529; called by muse, mutect2, varscan2
- LGALS2 | c.148T>A p.F50I | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV50758439; called by muse, mutect2, varscan2
- LPAR6 | c.67A>T p.M23L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99926673; called by muse, mutect2, varscan2
- LPAR6 | c.66C>A p.C22* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV99926674; called by muse, mutect2, varscan2
- LPO | c.1535T>A p.L512Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV51862350; called by muse, mutect2, varscan2
- LRFN5 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53243316, COSV53273551; called by muse, mutect2, varscan2
- LRGUK | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53643253; called by muse, mutect2, varscan2
- LRIF1 | c.149A>T p.K50M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV63898424; called by muse, mutect2, varscan2
- LRP12 | c.2345G>T p.G782V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV52634211; called by muse, mutect2, varscan2
- LRP1B | c.13472G>T p.G4491V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67271084; called by muse, mutect2, varscan2
- LRP1B | c.6509G>T p.C2170F | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67232082, COSV67271088; called by muse, mutect2, varscan2
- LUZP1 | c.2475G>T p.Q825H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV56505089; called by muse, mutect2, varscan2
- LY75 | c.3412C>A p.L1138M | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55112508; called by muse, mutect2, varscan2
- LYPD6B | c.292A>T p.S98C (on ENST00000409029 / NM_001317004.1; = p.S122C on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV54520615; called by muse, mutect2, varscan2
- MAPKAPK3 | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100781778; called by muse, mutect2, varscan2
- MARCO | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV59058311; called by muse, mutect2, varscan2
- MCFD2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs768254017, COSV100109179; called by muse, mutect2, varscan2
- MFSD12 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV62597226, COSV62598487; called by muse, mutect2, varscan2
- MIIP | c.809A>G p.Q270R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750154144, COSV52428695; called by muse, mutect2, varscan2
- MKRN3 | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100091607; called by muse, mutect2, varscan2
- MPP3 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV68199183; called by muse, mutect2, varscan2
- MRPS31 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs1458886459, COSV60268855; called by muse, mutect2, varscan2
- MS4A2 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs750693474, COSV54013791; called by muse, mutect2, varscan2
- MSMO1 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV54971088; called by muse, mutect2, varscan2
- MTMR6 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67809747; called by muse, varscan2
- MUC16 | c.38740C>A p.P12914T | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.086); catalogued as rs1299493358, COSV67491183; called by muse, mutect2, varscan2
- MUC16 | c.32383T>A p.S10795T | Missense Mutation (SNP) | VAF 84/115 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV67491190; called by muse, mutect2, varscan2
- MYBL1 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72919207; called by muse, mutect2, varscan2
- MYLK | c.685G>T p.G229* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as COSV60621840; called by muse, mutect2, varscan2
- MYT1 | c.2396+2T>G p.X799_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV60512882; called by muse, mutect2, varscan2
- NBN | c.2185G>C p.V729L | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.817); catalogued as COSV55376794, COSV99619428; called by muse, mutect2, varscan2
- NELL1 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100124841; called by muse, mutect2, varscan2
- NEO1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56077789; called by muse, mutect2, varscan2
- NFATC3 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); catalogued as COSV60479161; called by muse, mutect2, varscan2
- NHLRC3 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV65463584; called by muse, mutect2, varscan2
- NLRP3 | c.371G>T p.R124I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV60219589, COSV60230524; called by muse, mutect2, varscan2
- NLRP3 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV60230533; called by muse, mutect2, varscan2
- NOX5 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.482); catalogued as COSV52995048; called by muse, mutect2, varscan2
- NTRK3 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as COSV58141619, COSV58142909; called by muse, mutect2, varscan2
- OPLAH | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70679229; called by muse, mutect2, varscan2
- OR10G9 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148745928, COSV66686707; called by muse, mutect2
- OR11A1 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV65821363; called by muse, mutect2, varscan2
- OR1J4 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV61590279; called by muse, mutect2, varscan2
- OR4A15 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV59034285; called by muse, mutect2, varscan2
- OR4C46 | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as rs1181890552, COSV60219215; called by muse, mutect2, varscan2
- OR51E1 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV67809970, COSV67810921; called by muse, mutect2, varscan2
- OR6C2 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 101/142 reads (71%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as COSV59515539, COSV59516873; called by muse, mutect2, varscan2
- OR6C75 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58553429; called by muse, mutect2, varscan2
- ORC5 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as COSV99857367; called by muse, mutect2, varscan2
- OSR2 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs202146539, COSV52555294, COSV52558803; called by muse, mutect2, varscan2
- PABPC1L | c.972+1G>T p.X324_splice | Splice Site (SNP) | VAF 25/46 reads (54%) | catalogued as COSV53842803; called by muse, mutect2, varscan2
- PADI1 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV100969262; called by muse, mutect2, varscan2
- PADI1 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100969264, COSV100969312; called by muse, mutect2, varscan2
- PAFAH2 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV65340196; called by muse, mutect2, varscan2
- PCDH1 | c.784A>T p.S262C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54619016; called by muse, mutect2, varscan2
- PCDH15 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.633); catalogued as COSV57387979; called by muse, mutect2, varscan2
- PCDH17 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as COSV64978787; called by muse, mutect2, varscan2
- PCDHA2 | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65370823; called by muse, mutect2, varscan2
- PCDHB10 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.036); catalogued as COSV53383473; called by muse, mutect2, varscan2
- PCDHB14 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.365); catalogued as COSV53391032, COSV99506248; called by muse, varscan2
- PCDHB14 | c.1893C>A p.S631R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as COSV99506252; called by muse, varscan2
- PCDHB15 | c.2263C>A p.L755M | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV51392077; called by muse, mutect2, varscan2
- PCDHB2 | c.1387C>A p.R463S | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV99164149, COSV99166535; called by muse, mutect2, varscan2
- PCDHB7 | c.2054C>A p.T685N | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50782656, COSV50811529; called by muse, mutect2, varscan2
- PCDHGB3 | c.880C>A p.L294M | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53895334; called by muse, mutect2, varscan2
- PCDHGB5 | c.1698C>G p.D566E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as COSV54025098; called by muse, mutect2, varscan2
- PCK1 | c.1187-1G>T p.X396_splice | Splice Site (SNP) | VAF 20/74 reads (27%) | catalogued as COSV60130948; called by muse, mutect2, varscan2
- PCNX1 | c.3566G>T p.W1189L | Missense Mutation (SNP) | VAF 90/104 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV53101331, COSV99031981; called by muse, mutect2, varscan2
- PDZRN3 | c.2161C>A p.L721M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55214584; called by muse, mutect2, varscan2
- PEG10 | c.130C>A p.L44I (on ENST00000482108 / NM_001040152.2; = p.L78I on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV101509972; called by muse, mutect2
- PIWIL3 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59997977; called by muse, mutect2, varscan2
- PKD1L1 | c.7916G>A p.C2639Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.497); catalogued as COSV51844958; called by muse, mutect2, varscan2
- PLCG2 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV100842618; called by muse, mutect2, varscan2
- PLXNA2 | c.5006G>T p.G1669V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs754683785, COSV65444597; called by muse, mutect2, varscan2
- PLXNA2 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs988414799, COSV65440163; called by muse, varscan2
- POLG | c.2126G>T p.R709L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51524979; called by muse, mutect2, varscan2
- POTEF | c.2320G>T p.G774C | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs755473566, COSV62544017; called by muse, mutect2, varscan2
- PRDM12 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV53391811; called by muse, mutect2, varscan2
- PRKN | c.1028C>A p.P343Q | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58203788, COSV58274029; called by muse, mutect2, varscan2
- PRM2 | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | PolyPhen benign (0.011); catalogued as COSV54113918; called by muse, mutect2
- PRMT6 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63656432; called by muse, mutect2
- PRUNE2 | c.5631G>T p.E1877D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV65047390; called by muse, mutect2, varscan2
- PRUNE2 | c.4055C>G p.A1352G | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV65040963, COSV65047396; called by muse, mutect2, varscan2
- PTPRT | c.1338C>A p.H446Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100630296; called by muse, mutect2, varscan2
- PTTG2 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54726886; called by muse, mutect2, varscan2
- PXDN | c.1552A>T p.T518S | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV53245665; called by muse, mutect2, varscan2
- QSOX2 | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62395245; called by muse, mutect2, varscan2
- RAI14 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV54302961; called by muse, mutect2, varscan2
- RALBP1 | c.1623G>T p.E541D | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50038130; called by muse, mutect2, varscan2
- RAPGEF3 | c.2011A>T p.T671S (on ENST00000389212; = p.T629S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV50235470; called by muse, mutect2, varscan2
- RBM14 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 94/140 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100036949; called by muse, mutect2, varscan2
- RBM27 | c.2254C>T p.L752F | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54594134; called by muse, mutect2, varscan2
- REG1A | c.65-1G>T p.X22_splice | Splice Site (SNP) | VAF 65/263 reads (25%) | catalogued as COSV52071470, COSV52071843; called by muse, mutect2, varscan2
- RELN | c.3578C>A p.P1193H | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV100634863; called by muse, mutect2, varscan2
- RELN | c.3577C>A p.P1193T | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.133); catalogued as COSV100634868; called by muse, mutect2, varscan2
- RELN | c.1149C>A p.S383R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.446); catalogued as COSV59031992; called by muse, mutect2, varscan2
- RFWD3 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63099339; called by muse, mutect2, varscan2
- RICTOR | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 40/122 reads (33%) | catalogued as COSV57130143; called by muse, varscan2
- RIMS2 | c.883del p.D295Tfs*15 (on ENST00000666250 / NM_001348490.2; = p.D103Tfs*15 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 28/103 reads (27%) | catalogued as COSV99169874; called by mutect2, pindel, varscan2
- RNPEP | c.1734C>G p.I578M | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.657); catalogued as COSV55242862, COSV55243961; called by muse, mutect2, varscan2
- ROBO1 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71398172; called by muse, mutect2, varscan2
- RTTN | c.6298G>T p.G2100C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55351680; called by muse, mutect2, varscan2
- RYR2 | c.2668C>A p.H890N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63693453, COSV63720348; called by muse, mutect2, varscan2
- RYR2 | c.6164C>A p.S2055Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV63671387; called by muse, mutect2
- RYR2 | c.9610G>A p.V3204I | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV63711518; called by muse, mutect2, varscan2
- RYR2 | c.13091C>A p.T4364N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.19); catalogued as COSV63711522; called by muse, mutect2, varscan2
- RYR3 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101214380; called by muse, mutect2
- RYR3 | c.6283C>T p.R2095C | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs918904409, COSV66807300; called by muse, mutect2, varscan2
- S1PR3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63981310; called by muse, mutect2, varscan2
- SCAP | c.1778C>A p.S593* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as COSV55565596; called by muse, mutect2, varscan2
- SCN10A | c.4976C>A p.T1659K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71860207, COSV71862620; called by muse, mutect2, varscan2
- SERPINA3 | c.1025A>G p.D342G | Missense Mutation (SNP) | VAF 77/83 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV67587093; called by muse, mutect2, varscan2
- SETD2 | c.2563A>T p.S855C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.41); catalogued as COSV57450801; called by muse, mutect2, varscan2
- SFTPA2 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV100958868, COSV64882872; called by muse, mutect2, varscan2
- SHOX2 | c.448G>T p.E150* (on ENST00000441443 / NM_006884.3; = p.E174* on NM_003030.4) | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV101273818, COSV67464718; called by muse, mutect2, varscan2
- SIPA1L2 | c.3413G>A p.W1138* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV53399194; called by muse, mutect2, varscan2
- SKOR1 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV58249760; called by muse, mutect2, varscan2
- SLA | c.806C>A p.S269* (on ENST00000338087 / NM_001045556.3; = p.S309* on NM_006748.4) | Nonsense Mutation (SNP) | VAF 67/237 reads (28%) | catalogued as COSV99603035; called by muse, mutect2, varscan2
- SLC24A5 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV58319409, COSV99050379; called by muse, mutect2
- SLC38A8 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.592); catalogued as rs777130271, COSV55309350; called by muse, mutect2, varscan2
- SLC45A1 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV57099969; called by muse, mutect2, varscan2
- SLC49A3 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.112); catalogued as rs139449222; called by muse, mutect2, varscan2
- SLC6A17 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100521519, COSV58996527; called by muse, mutect2, varscan2
- SLC7A13 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV99879189; called by muse, mutect2, varscan2
- SLC7A13 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99879193; called by muse, mutect2, varscan2
- SLC9C2 | c.3161T>G p.V1054G | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62949186; called by muse, mutect2, varscan2
- SLITRK3 | c.1327C>A p.R443S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV53847403, COSV53853131; called by muse, mutect2, varscan2
- SLITRK5 | c.2258C>A p.P753H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100280273, COSV61526016; called by muse, mutect2, varscan2
- SMARCC1 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV54386292; called by muse, mutect2, varscan2
- SOX14 | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100048333, COSV60163392; called by muse, varscan2
- SPDEF | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV65001699; called by muse, mutect2, varscan2
- SPEG | c.2452T>C p.S818P | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.979); catalogued as COSV56679108; called by muse, mutect2, varscan2
- SPRY3 | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57144308; called by muse, mutect2, varscan2
- SPTA1 | c.4076G>T p.G1359V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV63758845; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3410C>T p.T1137M | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs567322233, COSV59137579; called by muse, mutect2, varscan2
- SYNPO2 | c.3764G>T p.R1255M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100206206, COSV61116633; called by muse, mutect2, varscan2
- TARS3 | c.2146G>A p.V716I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV100255010; called by muse, mutect2, varscan2
- TARS3 | c.2146-1G>T p.X716_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100255014; called by muse, mutect2
- TBC1D19 | c.481-1G>T p.X161_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99336781; called by muse, mutect2
- TBR1 | c.713G>C p.S238T | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV67419130; called by muse, mutect2, varscan2
- TBX22 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV64787774; called by muse, mutect2, varscan2
- TECRL | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67090375; called by muse, mutect2, varscan2
- TFR2 | c.1568C>A p.P523H | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56156347; called by muse, mutect2, varscan2
- TG | c.4841G>A p.S1614N | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.094); catalogued as COSV55093026; called by muse, mutect2, varscan2
- TGIF2LX | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52215133, COSV99383481; called by muse, mutect2, varscan2
- THAP5 | c.554A>T p.N185I (on ENST00000415914 / NM_001130475.3; = p.N143I on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99974590; called by muse, mutect2, varscan2
- THSD7B | c.3624G>C p.R1208S (on ENST00000272643; = p.R1206S on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs758750294, COSV55734191; called by muse, mutect2, varscan2
- TLR7 | c.1372C>A p.Q458K | Missense Mutation (SNP) | VAF 70/85 reads (82%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV66125489; called by muse, mutect2, varscan2
- TLX1 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs891153209, COSV100930105; called by muse, mutect2, varscan2
- TMC1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.724); catalogued as COSV52784712; called by muse, mutect2, varscan2
- TMCO4 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV99230442; called by muse, mutect2, varscan2
- TMCO4 | c.1634A>T p.Q545L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99230445; called by muse, mutect2, varscan2
- TMEM132B | c.2962A>G p.S988G | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54768652; called by muse, mutect2, varscan2
- TMPRSS11E | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV59521043; called by muse, mutect2, varscan2
- TMPRSS15 | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV99518398; called by muse, mutect2, varscan2
- TNXB | c.11153T>A p.V3718E (on ENST00000647633; = p.V3471E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64488259; called by muse, mutect2, varscan2
- TPTE | c.1150G>T p.G384* (on ENST00000618007 / NM_199261.4; = p.G366* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as rs142165446; called by muse, mutect2, varscan2
- TRPM6 | c.4352G>T p.G1451V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV62521625, COSV62522468; called by muse, mutect2, varscan2
- TTLL11 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58652614; called by muse, mutect2, varscan2
- UGT2B10 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as COSV55323091, COSV55323296; called by muse, mutect2, varscan2
- ULK4 | c.3368C>G p.S1123C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs532435333, COSV57222461; called by muse, mutect2, varscan2
- UNC5A | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56172168; called by muse, mutect2, varscan2
- UPP2 | c.620C>A p.P207Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV50049050; called by muse, mutect2, varscan2
- VWA8 | c.5636G>T p.R1879L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65000244; called by muse, mutect2, varscan2
- VWCE | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV57115286; called by muse, mutect2, varscan2
- WT1 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV100188321, COSV60082551; called by muse, mutect2, varscan2
- XXYLT1 | c.362C>A p.A121E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV58755532; called by muse, mutect2, varscan2
- YTHDF1 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64833886; called by muse, mutect2, varscan2
- ZBTB11 | c.3072A>T p.L1024F | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57246874; called by muse, mutect2, varscan2
- ZC3HAV1 | c.837del p.S280Afs*52 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as COSV54297154; called by mutect2, pindel, varscan2
- ZIC4 | c.776C>A p.T259N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67171251, COSV67174038; called by muse, mutect2, varscan2
- ZIC4 | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV67174046; called by muse, mutect2, varscan2
- ZNF229 | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as COSV52164720; called by muse, mutect2, varscan2
- ZNF236 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53497014; called by muse, mutect2, varscan2
- ZNF484 | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60259555; called by muse, mutect2, varscan2
- ZNF485 | c.1162G>T p.G388W | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62425964; called by muse, mutect2, varscan2
- ZNF536 | c.3752C>A p.P1251Q | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV62833425; called by muse, mutect2, varscan2
- ZNF648 | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV60572656; called by muse, mutect2, varscan2
- ZNF665 | c.94G>C p.D32H (on ENST00000600412; = p.D97H on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/155 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV67217416, COSV67217556; called by muse, mutect2, varscan2
- ZNF671 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV58053105, COSV58054320; called by muse, mutect2, varscan2
- ZNF783 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65186759; called by muse, mutect2, varscan2
- ZNF81 | c.1312G>T p.G438* | Nonsense Mutation (SNP) | VAF 28/33 reads (85%) | catalogued as COSV58578481; called by muse, mutect2, varscan2
- ZNF98 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV63339672; called by muse, mutect2, varscan2
- ZPBP | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs755095832, COSV50433353; called by muse, mutect2, varscan2
- AGAP1 | c.386dup p.E130Gfs*20 | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- AKAP6 | c.1631del p.P544Hfs*88 | Frame Shift Del (DEL) | VAF 75/115 reads (65%) | called by mutect2, pindel, varscan2
- ARRDC4 | c.425_426del p.V142Afs*11 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by pindel, varscan2
- BSX | c.267del p.M89Ifs*66 | Frame Shift Del (DEL) | VAF 28/54 reads (52%) | called by mutect2, pindel
- CALD1 | c.2175del p.T726Lfs*13 (on ENST00000361675 / NM_033138.4; = p.T471Lfs*13 on NM_004342.7) | Frame Shift Del (DEL) | VAF 32/64 reads (50%) | called by mutect2, pindel, varscan2
- CDC37L1 | c.1012_1013del p.*338Ifs*44 | Frame Shift Del (DEL) | VAF 47/84 reads (56%) | called by pindel, varscan2
- DGUOK | c.255dup p.A86Sfs*43 | Frame Shift Ins (INS) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- GFPT1 | c.844del p.S282Vfs*4 (on ENST00000357308 / NM_001244710.2; = p.S264Vfs*4 on NM_002056.4) | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | called by mutect2, pindel, varscan2
- GPR45 | c.492del p.S166Rfs*94 | Frame Shift Del (DEL) | VAF 14/27 reads (52%) | called by mutect2, pindel, varscan2
- HFM1 | c.1539_1540del p.N514Lfs*12 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- IGF2BP2 | c.1176del p.A393Lfs*38 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- IGLV3-16 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- IGLV7-43 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- LCP1 | c.659del p.K220Sfs*29 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- MZT2A | c.350del p.G117Efs*? | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by pindel, varscan2
- NAT1 | c.169dup p.D57Gfs*29 | Frame Shift Ins (INS) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- NFKB1 | c.444dup p.V149Sfs*3 (on ENST00000394820 / NM_001382627.1; = p.V150Sfs*3 on NM_003998.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 21/102 reads (21%) | called by mutect2, pindel, varscan2
- OTOA | c.615_616del p.E206Gfs*4 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by pindel, varscan2
- PGK2 | c.813del p.A273Hfs*6 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by mutect2, pindel*, varscan2
- PLAGL2 | c.30del p.W11Gfs*15 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- RBM10 | c.776del p.P259Hfs*7 | Frame Shift Del (DEL) | VAF 7/9 reads (78%) | called by mutect2, varscan2
- SCN5A | c.5490del p.N1831Tfs*3 (on ENST00000333535 / NM_198056.3; = p.N1830Tfs*3 on NM_000335.5) | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | called by mutect2, pindel*, varscan2
- SFTPA2 | c.35del p.L12* | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D19 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2
- TLN2 | c.960G>A p.E320= | Splice Region (SNP) | VAF 7/14 reads (50%) | called by muse, varscan2
- TRAPPC12 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2
- TTN | c.38330_38331del p.K12777Sfs*6 (on ENST00000591111; = p.K5353Sfs*6 on NM_003319.4) | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | called by mutect2, pindel, varscan2
- WNT2B | c.1012_1024del p.M338Efs*92 (on ENST00000369684 / NM_024494.3; = p.M319Efs*92 on NM_004185.4) | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- ZBTB14 | c.1315del p.A439Qfs*8 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- ZNF280B | c.394del p.Q132Kfs*14 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | called by mutect2, pindel, varscan2
- ACACB | c.1002G>T p.L334= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as COSV58145420; called by muse, mutect2, varscan2
- ACACB | c.5163G>T p.P1721= | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV58133845, COSV58145445; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2679G>T p.T893= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as rs369204296, COSV65892009, COSV65899528; called by muse, mutect2, varscan2
- ADGRD1 | c.1107G>A p.T369= | Silent (SNP) | VAF 57/76 reads (75%) | catalogued as rs532956146, COSV55447877; called by muse, mutect2, varscan2
- AEBP1 | c.1059C>T p.T353= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs773837826, COSV56256328; called by muse, mutect2, varscan2
- AFMID | c.198C>T p.V66= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV59977505; called by muse, mutect2, varscan2
- AGRN | c.2592G>A p.G864= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV65072164; called by muse, mutect2, varscan2
- AHCY | c.969G>A p.P323= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs746288986, COSV54154459; called by muse, mutect2, varscan2
- AHSG | c.273G>T p.V91= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV56609279; called by muse, mutect2, varscan2
- ANKZF1 | c.768A>T p.S256= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55478749; called by muse, mutect2, varscan2
- ARFGEF2 | c.2856C>T p.S952= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV64214922; called by muse, mutect2, varscan2
- ARHGAP25 | c.6C>T p.S2= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV54908623; called by muse, mutect2, varscan2
- C1orf87 | c.102A>T p.P34= | Silent (SNP) | VAF 23/213 reads (11%) | catalogued as COSV64598644; called by muse, mutect2, varscan2
- CD1D | c.681A>T p.S227= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV63809988; called by muse, mutect2, varscan2
- CDX4 | c.354T>C p.P118= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs1326799801, COSV65171892; called by muse, mutect2, varscan2
- CEMIP | c.1368G>T p.V456= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV54999709, COSV99585829; called by muse, mutect2, varscan2
- CFHR4 | c.1623A>T p.T541= (on ENST00000367416 / NM_001201551.2; = p.T295= on NM_006684.5) | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV52235264; called by muse, mutect2, varscan2
- CHUK | c.624G>T p.G208= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV64918698; called by muse, mutect2, varscan2
- CNBD2 | c.1008C>A p.I336= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV62587927; called by muse, mutect2, varscan2
- CSMD1 | c.1782G>A p.G594= (on ENST00000520002; = p.G593= on NM_033225.6) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1285255643, COSV59379064; called by muse, mutect2, varscan2
- CYP2A7 | c.471C>T p.I157= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs534396743, COSV52498541; called by muse, mutect2, varscan2
- DBF4 | c.861G>A p.L287= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs753347200, COSV55995720; called by muse, mutect2, varscan2
- DDB1 | c.2433A>G p.E811= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs1179983762, COSV57105543; called by muse, mutect2, varscan2
- DNAJC10 | c.357T>C p.R119= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV51146210; called by muse, mutect2, varscan2
- DNAJC5B | c.348C>A p.I116= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV99395919; called by muse, mutect2, varscan2
- DOCK10 | c.363T>C p.H121= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV51426815; called by muse, mutect2, varscan2
- EBF3 | c.903G>A p.V301= (on ENST00000355311 / NM_001375392.1; = p.V292= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1200628039, COSV62481398; called by muse, mutect2, varscan2
- ELAPOR2 | c.993A>G p.Q331= (on ENST00000450689 / NM_001142749.3; = p.Q164= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs1433669659, COSV51891518; called by muse, mutect2, varscan2
- EPHX2 | c.570G>T p.L190= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV66846006; called by muse, mutect2, varscan2
- ERBB2 | c.474C>T p.N158= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs768502081, COSV54082180; called by muse, mutect2, varscan2
- F13A1 | c.51C>T p.P17= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as rs972426755, COSV53566803; called by muse, mutect2, varscan2
- F7 | c.1263C>A p.I421= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60647941; called by muse, mutect2, varscan2
- FGFR1 | c.1563A>G p.T521= (on ENST00000447712 / NM_023110.3; = p.T519= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/99 reads (71%) | catalogued as rs958467124, COSV58343785; called by muse, mutect2, varscan2
- FHOD3 | c.867G>T p.L289= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99942184; called by muse, mutect2, varscan2
- FLG | c.7374T>A p.G2458= | Silent (SNP) | VAF 159/346 reads (46%) | catalogued as COSV64248383; called by muse, mutect2, varscan2
- GJA4 | c.858C>A p.S286= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100654754; called by muse, mutect2, varscan2
- GORAB | c.930A>G p.P310= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV63028901; called by muse, mutect2, varscan2
- GRIN2B | c.678C>A p.P226= | Silent (SNP) | VAF 126/180 reads (70%) | catalogued as COSV74207612; called by muse, mutect2, varscan2
- HES3 | c.543C>A p.P181= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100928605; called by muse, mutect2, varscan2
- HOXA6 | c.618C>G p.R206= | Silent (SNP) | VAF 47/187 reads (25%) | catalogued as COSV56073698; called by muse, mutect2, varscan2
- HRG | c.1011C>A p.A337= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV51648143; called by muse, mutect2, varscan2
- KAT2A | c.930C>T p.R310= | Silent (SNP) | VAF 62/85 reads (73%) | catalogued as COSV56792874; called by muse, mutect2, varscan2
- KIF1A | c.1080C>A p.I360= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57500785; called by muse, mutect2, varscan2
- KLHL17 | c.1023G>A p.G341= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs893484734, COSV58533473; called by muse, mutect2
- KRT1 | c.843G>A p.E281= | Silent (SNP) | VAF 33/45 reads (73%) | catalogued as COSV52869137, COSV99358815, COSV99358859; called by muse, mutect2, varscan2
- KRTAP5-5 | c.618A>T p.S206= | Silent (SNP) | VAF 111/178 reads (62%) | catalogued as COSV68785688; called by muse, mutect2, varscan2
- LAMB4 | c.3603T>C p.A1201= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV52730186; called by muse, mutect2, varscan2
- LGI1 | c.1587C>T p.S529= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV65059173; called by muse, mutect2, varscan2
- LILRB5 | c.387G>T p.L129= | Silent (SNP) | VAF 50/61 reads (82%) | catalogued as COSV60260862; called by muse, mutect2, varscan2
- LRFN2 | c.987G>T p.L329= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV57834118; called by muse, mutect2, varscan2
- LVRN | c.2958A>G p.L986= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV63498300; called by muse, mutect2, varscan2
- MAB21L3 | c.771G>A p.R257= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1378475869, COSV65674494; called by muse, mutect2, varscan2
- MAGEL2 | c.3429C>G p.V1143= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV58568989; called by muse, mutect2, varscan2
- MB21D2 | c.1254C>A p.V418= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV101165177; called by muse, mutect2, varscan2
- MMD | c.654G>T p.V218= | Silent (SNP) | VAF 69/90 reads (77%) | catalogued as COSV50436334; called by muse, mutect2, varscan2
- MRGPRF | c.210C>G p.G70= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100307920; called by muse, mutect2
- MUC16 | c.24921C>T p.T8307= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1483226523, COSV67491195; called by muse, mutect2, varscan2
- MXRA5 | c.6684T>A p.G2228= | Silent (SNP) | VAF 39/48 reads (81%) | catalogued as COSV54249281; called by muse, mutect2, varscan2
- MYO9A | c.2571A>G p.L857= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV61857298; called by muse, mutect2, varscan2
- MYT1 | c.1953A>T p.P651= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV60512859; called by muse, varscan2
- NCALD | c.15C>T p.N5= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV55275063; called by muse, mutect2, varscan2
- NELFA | c.588C>T p.T196= (on ENST00000542778; = p.T185= on NM_005663.5) | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs536359664, COSV61605143; called by muse, mutect2
- NRXN3 | c.366G>T p.V122= | Silent (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2
- OR13A1 | c.48C>T p.P16= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV65573383; called by muse, mutect2, varscan2
- OR9A4 | c.516T>C p.N172= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV71886038; called by muse, mutect2, varscan2
- OSBPL7 | c.864C>T p.T288= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as COSV50115037; called by muse, mutect2, varscan2
- OVCH1 | c.1938G>A p.R646= | Silent (SNP) | VAF 74/100 reads (74%) | catalogued as rs529800856, COSV58967885; called by muse, mutect2, varscan2
- PCDHA13 | c.1374C>A p.P458= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV56542755; called by muse, mutect2, varscan2
- PCDHGA7 | c.546G>A p.V182= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54025083; called by muse, mutect2, varscan2
- PCDHGB3 | c.2055G>A p.Q685= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs777753711, COSV54025064, COSV99544757; called by muse, mutect2, varscan2
- PDPR | c.435A>T p.A145= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99848853; called by mutect2, varscan2
- PEAR1 | c.2697C>A p.G899= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV52775659; called by muse, mutect2, varscan2
- PIK3C3 | c.117G>T p.L39= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56284196; called by muse, mutect2, varscan2
- PLCG2 | c.876G>A p.T292= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs375222873, COSV100842619; called by muse, mutect2, varscan2
- PLCL1 | c.2616T>C p.Y872= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as COSV70872530; called by muse, mutect2, varscan2
- POLA1 | c.2928G>A p.V976= | Silent (SNP) | VAF 29/38 reads (76%) | catalogued as COSV66890510; called by muse, mutect2, varscan2
- POLR1B | c.162C>T p.L54= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV51976512; called by muse, mutect2, varscan2
- PPP1R21 | c.654C>G p.S218= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV54288729; called by muse, mutect2, varscan2
- PRDM9 | c.18C>T p.S6= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1484683896, COSV57012749; called by muse, mutect2, varscan2
- PRRC2A | c.2697C>T p.G899= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV65688842; called by muse, mutect2, varscan2
- PRSS36 | c.639C>T p.P213= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs200651342; called by muse, mutect2, varscan2
- PSG7 | c.465T>C p.N155= | Silent (SNP) | VAF 137/169 reads (81%) | catalogued as rs374884624, COSV68446182; called by muse, mutect2, varscan2
- PSKH2 | c.129G>T p.A43= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs778814889, COSV52612512; called by muse, mutect2, varscan2
- RP1L1 | c.207C>A p.S69= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV61447567; called by muse, mutect2, varscan2
- SAMD9L | c.2763C>T p.L921= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV59085013; called by muse, mutect2, varscan2
- SCN4A | c.5286G>T p.G1762= | Silent (SNP) | VAF 40/56 reads (71%) | catalogued as rs1249593659, COSV71128917; called by muse, mutect2, varscan2
- SIX1 | c.633G>T p.P211= | Silent (SNP) | VAF 84/99 reads (85%) | catalogued as COSV99903478; called by muse, mutect2, varscan2
- SLC17A1 | c.777T>G p.L259= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV55082037; called by muse, mutect2, varscan2
- SLC36A3 | c.1311C>T p.I437= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs746702662, COSV58857944; called by muse, mutect2, varscan2
- SLC6A17 | c.654G>C p.S218= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100521516; called by muse, mutect2, varscan2
- SP140 | c.24G>T p.G8= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV59447044, COSV59454655; called by muse, mutect2, varscan2
- STAMBPL1 | c.390C>T p.N130= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs750145963, COSV64222564; called by muse, mutect2, varscan2
- TAL1 | c.615G>T p.G205= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53748450; called by muse, mutect2, varscan2
- TDRD5 | c.33G>T p.L11= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV54249841; called by muse, mutect2, varscan2
- TGM7 | c.1362G>A p.E454= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV71773132; called by muse, mutect2, varscan2
- THSD7B | c.1791C>A p.P597= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV55734176; called by muse, mutect2, varscan2
- TMEM63C | c.1830G>C p.V610= | Silent (SNP) | VAF 31/201 reads (15%) | catalogued as COSV53608513; called by muse, mutect2, varscan2
- TNFRSF1B | c.147A>T p.T49= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV66165094; called by muse, mutect2, varscan2
- TRAV25 | c.4C>T p.L2= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- TSC1 | c.1743C>T p.F581= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53770565; called by muse, mutect2, varscan2
- TTYH3 | c.1233C>T p.H411= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs889295806, COSV51862913; called by muse, mutect2, varscan2
- UNC45B | c.1008G>T p.G336= | Silent (SNP) | VAF 82/118 reads (69%) | catalogued as rs781343218, COSV52100368; called by muse, mutect2, varscan2
- USP43 | c.2130G>T p.R710= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as rs1417747054, COSV53306705; called by muse, mutect2, varscan2
- VASN | c.891C>T p.R297= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99228096; called by muse, mutect2, varscan2
- WDR54 | c.930T>C p.F310= | Silent (SNP) | VAF 49/161 reads (30%) | catalogued as COSV51966055; called by muse, mutect2, varscan2
- WNT10A | c.453G>T p.L151= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99297575; called by muse, mutect2, varscan2
- ZFHX4 | c.9096T>A p.I3032= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV51494198; called by muse, mutect2, varscan2
- ZIM2 | c.1512C>T p.G504= | Silent (SNP) | VAF 38/52 reads (73%) | catalogued as COSV55631065, COSV99689257; called by muse, mutect2, varscan2
- ZNF19 | c.186G>T p.L62= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99867690; called by muse, mutect2, varscan2
- ZNF416 | c.423G>A p.K141= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as COSV52185742; called by muse, mutect2, varscan2
- ZNF449 | c.1306A>C p.R436= | Silent (SNP) | VAF 54/71 reads (76%) | catalogued as COSV59347923, COSV59348055; called by muse, mutect2, varscan2
- ZNF451 | c.1698A>G p.V566= | Silent (SNP) | VAF 57/102 reads (56%) | catalogued as COSV100675094; called by muse, mutect2, varscan2
- ZNF497 | c.1452C>T p.N484= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV99568651; called by muse, mutect2, varscan2
- AC244258.1 | n.413C>A | RNA (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- BMP2K | c.1951+40del | Intron (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- CCNQP1 | n.231C>T | RNA (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+23G>T | Intron (SNP) | VAF 51/99 reads (52%) | catalogued as COSV54573425; called by muse, mutect2, varscan2
- CNOT1 | c.3523-933G>C | Intron (SNP) | VAF 19/88 reads (22%) | catalogued as COSV99801134; called by muse, mutect2, varscan2
- FAM135A | c.823+4081A>G | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99526625; called by muse, mutect2, varscan2
- FLNB | c.6368-657C>A | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99914663; called by muse, mutect2, varscan2
- MIR548I2 | n.106G>T | RNA (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- MIRLET7A2 | n.2G>C | RNA (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- RIMS2 | c.4064-21258C>A | Intron (SNP) | VAF 26/39 reads (67%) | catalogued as COSV99196376; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792471 G>A | 3'Flank (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.798-4413G>T | Intron (SNP) | VAF 17/41 reads (41%) | catalogued as COSV51516114; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1910C>T | Intron (SNP) | VAF 16/76 reads (21%) | catalogued as rs371088689; called by muse, mutect2, varscan2
- TRIM41 | c.*607_*610del | 3'UTR (DEL) | VAF 11/41 reads (27%) | catalogued as rs757457170; called by mutect2, pindel, varscan2
- UBTFL2 | n.348G>T | RNA (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
